Somatic mutation profile of tumor specimen TCGA-BP-4985-01A (aliquot TCGA-BP-4985-01A-01D-1462-08) from TCGA case TCGA-BP-4985, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 72.9 years (26,611 days).
Specimen TCGA-BP-4985-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 669ea788-7e26-4f8d-a7df-84940a1a9133.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4985-11A (Solid Tissue Normal), aliquot TCGA-BP-4985-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf4d28c2-41f8-457e-90c5-ea7bd8459e85

The open-access MAF lists 96 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Frame Shift Del 5, In Frame Del 2, Intron 2, Nonsense Mutation 2, 5'Flank 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs1558474706, COSV67676236; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55293401; called by muse, mutect2
- ABCA13 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1436907195, COSV70033475; called by muse, mutect2
- AHCYL1 | c.364A>C p.I122L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV63208984; called by muse, mutect2, varscan2
- AHNAK | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57218996; called by muse, mutect2
- ALG10B | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 220/531 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.524); catalogued as COSV58143751, COSV58144835; called by muse, mutect2, varscan2
- ALOX5 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954471371, COSV65553126; called by muse, mutect2
- APOBEC4 | c.589G>T p.V197F | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100426104, COSV58018025; called by muse, mutect2, varscan2
- ATP13A3 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV55466520; called by muse, mutect2, varscan2
- CCDC183 | c.1253T>C p.M418T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as rs1358035652, COSV61037137; called by muse, mutect2
- CTNNA2 | c.2744C>A p.P915H (on ENST00000402739 / NM_001282597.3; = p.P867H on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58144680; called by muse, mutect2, varscan2
- DCAF11 | c.1378T>A p.C460S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV58109706; called by muse, mutect2
- DISP2 | c.3932A>C p.D1311A | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV51127910; called by muse, mutect2, varscan2
- DNAH2 | c.5434A>G p.T1812A | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66721843; called by muse, mutect2
- DNAH9 | c.4479G>C p.E1493D | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV52358377; called by muse, mutect2, varscan2
- ELOVL4 | c.223A>T p.M75L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757345615, COSV63954199; called by muse, mutect2, varscan2
- ETNPPL | c.950G>C p.C317S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV56596409; called by muse, mutect2, varscan2
- FAM136A | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50682894; called by muse, mutect2, varscan2
- GABRG1 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54957052; called by muse, mutect2, varscan2
- GRIN2A | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs749504561, COSV58028771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCA2A | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.448); catalogued as COSV63691397; called by muse, mutect2, varscan2
- HNRNPLL | c.1105A>G p.K369E | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV55368175; called by muse, mutect2, varscan2
- HTT | c.5927G>T p.C1976F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61864764; called by muse, mutect2, varscan2
- IBTK | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60394088; called by muse, mutect2, varscan2
- IL1RAP | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs770882561, COSV50764558; called by muse, mutect2, varscan2
- IQCA1 | c.1367A>C p.D456A | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV54505808; called by muse, mutect2, varscan2
- IQUB | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV61240355; called by muse, mutect2, varscan2
- IRS2 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.067); catalogued as COSV65479489; called by muse, mutect2, varscan2
- KATNIP | c.4473C>G p.F1491L | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV55177481, COSV55184875; called by muse, mutect2
- KCNH6 | c.2230T>G p.S744A | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59004893; called by muse, mutect2
- LARS1 | c.1637G>A p.C546Y (on ENST00000394434 / NM_020117.11; = p.C519Y on NM_016460.3) | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV50979826; called by muse, mutect2, varscan2
- LLGL2 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201300652, COSV51364432; called by muse, mutect2, varscan2
- MAP4 | c.2759T>A p.L920H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as COSV53139455; called by muse, mutect2, varscan2
- MAPK8IP2 | c.457A>C p.N153H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50501263; called by muse, mutect2, varscan2
- MYOF | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63706557; called by muse, mutect2, varscan2
- MYPN | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV62735332; called by muse, mutect2, varscan2
- OLFM3 | c.142C>G p.P48A (on ENST00000338858 / NM_001288821.1; = p.P28A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58800543; called by muse, mutect2, varscan2
- OTOGL | c.6060T>A p.D2020E (on ENST00000547103; = p.D2011E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54019104; called by muse, mutect2, varscan2
- PARP14 | c.3944T>C p.L1315S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71735007; called by muse, mutect2, varscan2
- PBRM1 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 93/242 reads (38%) | catalogued as COSV56285364, COSV99967886; called by muse, mutect2, varscan2
- PCNX3 | c.1355G>A p.C452Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV58420530; called by muse, mutect2, varscan2
- PHF12 | c.2653A>T p.I885F | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV60455786; called by muse, mutect2, varscan2
- POLR2I | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV52900439; called by muse, mutect2, varscan2
- PRPSAP1 | c.626C>G p.A209G | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV61211712; called by muse, mutect2
- PTOV1 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV55588875; called by muse, mutect2, varscan2
- RANBP2 | c.2903A>G p.Q968R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51703454; called by muse, mutect2, varscan2
- RCN2 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58031629; called by muse, mutect2, varscan2
- SEMA3D | c.638C>G p.T213S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as COSV52397413; called by muse, mutect2, varscan2
- SLC4A11 | c.1384T>C p.W462R | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs757935922, COSV66262589; called by muse, mutect2
- SNRNP70 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs138012907, COSV55506144; called by muse, mutect2
- SPECC1 | c.436C>A p.H146N | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV54961105; called by muse, mutect2, varscan2
- STAG2 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 43/64 reads (67%) | catalogued as COSV54356853; called by muse, mutect2, varscan2
- SWT1 | c.2674T>C p.C892R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV62256649; called by muse, mutect2, varscan2
- TAB2 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53853518; called by muse, mutect2, varscan2
- TCTE1 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs770396213, COSV65255810; called by muse, mutect2
- TMTC2 | c.1239C>G p.F413L | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58274313; called by muse, mutect2
- TRPS1 | c.2122C>G p.L708V (on ENST00000220888 / NM_001330599.2; = p.L721V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55248991; called by muse, mutect2
- TYK2 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53388876; called by muse, mutect2, varscan2
- VPS13B | c.4780A>C p.N1594H | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62147632; called by muse, mutect2, varscan2
- WASL | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56134406; called by muse, mutect2, varscan2
- ZBTB21 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60404737; called by muse, mutect2
- ARMC5 | c.118del p.L40* | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- BAP1 | c.2033_2046del p.F678Cfs*34 | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- CLSTN3 | c.1550dup p.L517Ffs*40 | Frame Shift Ins (INS) | VAF 24/121 reads (20%) | called by mutect2, pindel, varscan2
- IFI44L | c.868_876del p.R290_Q292del | In Frame Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- PPP4R3B | c.1926del p.F642Lfs*2 (on ENST00000616407 / NM_001122964.3; = p.F557Lfs*2 on NM_020463.4) | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel
- TET1 | c.6222_6224del p.K2074del | In Frame Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- UGT2B7 | c.245_248del p.T82Kfs*40 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- USP11 | c.1480del p.R494Gfs*47 (on ENST00000218348; = p.R451Gfs*47 on NM_001371072.1) | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- AQR | c.1974G>A p.R658= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV50039004, COSV99333505; called by muse, mutect2, varscan2
- C11orf1 | c.384T>C p.P128= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV52789330; called by muse, mutect2, varscan2
- DOP1B | c.2289C>T p.F763= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs1569037440, COSV67694046; called by muse, mutect2, varscan2
- FZD2 | c.1446C>T p.Y482= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV59529183, COSV59529410; called by muse, mutect2, varscan2
- GDPGP1 | c.939G>T p.L313= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV61575888; called by muse, mutect2, varscan2
- HPF1 | c.531G>A p.T177= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs761974582, COSV66422335; called by muse, mutect2
- MPRIP | c.2652C>A p.G884= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV57927560; called by muse, mutect2, varscan2
- MROH7 | c.3148C>T p.L1050= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1206901943, COSV59874264; called by muse, mutect2
- MUC16 | c.19806T>C p.S6602= | Silent (SNP) | VAF 91/240 reads (38%) | catalogued as COSV67476614; called by muse, mutect2, varscan2
- OR2T8 | c.255C>A p.T85= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs766136692, COSV60663383; called by muse, mutect2
- PCDHB11 | c.198G>C p.V66= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV53380890; called by muse, mutect2, varscan2
- PLAC9 | c.210G>C p.L70= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV64840604, COSV64840643; called by muse, mutect2, varscan2
- PPP2R1B | c.933G>A p.R311= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as rs1555049134, COSV59536348; called by muse, mutect2
- RIPK3 | c.240G>A p.E80= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV53476179; called by muse, mutect2, varscan2
- SLC7A13 | c.309G>A p.L103= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV52535490, COSV52536488; called by muse, mutect2, varscan2
- TM4SF20 | c.465T>A p.T155= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV58819009; called by muse, mutect2, varscan2
- TMEM67 | c.66G>A p.V22= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as rs1211790786, COSV60041431; called by muse, mutect2
- TREH | c.783C>T p.N261= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV50622743; called by muse, mutect2, varscan2
- VEZF1 | c.903C>A p.I301= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV51969302; called by muse, mutect2, varscan2
- WASHC2C | c.1023C>T p.F341= | Silent (SNP) | VAF 30/558 reads (5%) | catalogued as rs782588301; called by muse, mutect2
- ZC3HAV1 | c.1245C>T p.G415= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as COSV54297616; called by muse, mutect2, varscan2
- ZNF665 | c.1113C>A p.G371= (on ENST00000600412; = p.G436= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV67216040; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503144 del T | 5'Flank (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- AP3S1 | chr5:115841566 A>T | 5'Flank (SNP) | VAF 56/208 reads (27%) | catalogued as COSV57243376; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37165636 T>C | 3'Flank (SNP) | VAF 27/221 reads (12%) | catalogued as COSV57065319; called by muse, mutect2, varscan2
- DTNA | c.1094+1385G>T | Intron (SNP) | VAF 27/152 reads (18%) | catalogued as COSV52011345, COSV99310507; called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-11970G>T | Intron (SNP) | VAF 21/184 reads (11%) | catalogued as COSV62626476; called by muse, mutect2, varscan2
